Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACPV, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACPV-TTP1-A (Primary Tumor).

[page 1 of 2]
Sample sent as:

1. Upper lobe, extemporaneous examination.

2. Lymph node N 10

3. Lymph node N 11

4. Lymph node N 11

5. Lymph node N 11

6. Lymph node N 12

7. Intermediate bronco lymph node 1

8. Intermediate bronco lymph node 2

9. Intermediate artery lymph node

10. Lymph node N 4

11. Lymph node N 7

12. Lymph node N 8

Ⓡ lung, per TSS. @

CDDP-YP-ACPV-01-PR

**Macroscopic report:**

1. Lung lobe of cm 16x9x3 that sub pleural presents grayish nodule of hard consistency cm

2.7.

Remaining parenchyma macroscopically undamaged.

Extemporaneous diagnosis (E03/1066): adenocarcinoma

2. Four fragments of anthracotic lymph node, the largest one of cm 0.8

3. Un lymph node fragment of cm 0.5

4. Un lymph node fragment of cm 0.5

5. Un lymph node fragment of cm 0.4

6. Two lymph node fragments, the largest one of cm 1

7. Un lymph node fragment of cm 0.6

8. Un lymph node fragment of cm 1

9. Un lymph node fragment of cm 1.8

10. Un lymph node fragment of cm 0.6

11. Two lymph node fragments, , the largest one of cm 0.5

12. Un lymph node of cm 0.8

ICB-0-3

adenocarcinoma with mixed subtypes
8255/3

Site: Ⓡ lung, upper lobe C34.1

ICB-10

C 34.11

hw
12/14/16

Microscopic report:

1-12 Confirming the diagnosis expressed in the course of extemporaneous examination. Case of adenocarcinoma proliferation with sometimes cribriform and papillary aspects, mucin-secreting, widely necrotic, which in some areas shows aspects of a signet ring cell. The neoplasm type pattern alternates between frankly adeno components, a pattern of solid type, in large nests sometimes centrally necrotic, represent portions of cellular elements with weakly eosinophilic cytoplasm, rounded or slightly irregular nucleus, chromatin finely dispersed with obvious nucleolus. the neoplasm infiltrates extensively the lung parenchyma, it forms mucus lakes, and evokes desmoplastic stromal reaction. In the areas of necrosis they are observed optically empty spaces, needle-like, referring to cholesteric material deposits.

[page 2 of 2]
The neoplastic component tendency to squamous differentiation. Focal infiltration of the visceral pleura. Endo alveolar neoplasm diffusion, peri neoplastic obstructive pneumonia.

Infiltration of the vascular wall of some small intratumoral blood vessels without however intraluminal invasion.

Broncho: to level section taken from the surgical specimen and hilar lymph node isolated free from neoplasm.

No evidence of metastases in the examined lymph nodes.

Findings and histopathological diagnosis

1.-12 Mucin-secreting adenocarcinoma with papillary and solid aspects, infiltrating. Peritumoral obstructive pneumonia. Focal infiltration of the visceral pleura. Free from neoplasm the bronchus at the section and all the lymph nodes examined sent separately.

Source: NCI Genomic Data Commons file d680bb00-31d0-4375-9abb-a6103d927a45 (CDDP-ACPV-TTP1.91586A5F-4EEA-40CD-98D6-32AA7EC81383.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).